Surgical pathology report (de-identified scan), TCGA case TCGA-60-2711, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2711-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. LEVEL 7 SUBCARINAL
B. 4L LYMPH NODE
C. 2ND 4L LYMPH NODE
D. 4R LYMPH NODE
E. 2R LYMPH NODE
F. 11R LYMPH NODE LOWER LOBE
G. 11R MIDDLE LOBE
H. LEVEL 7
I. POSTERIOR PARITAL RIGHT LOWER LOBE ATTACHMENTS OF
TUMOR
J. RIGHT LOWER LOBE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Right lower lobe lung mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA-FSE: Lymph nodes, level 7, 4L, 2nd 4L, 4R, 2R, excision: Negative for carcinoma.

Right lower lobe: Bronchial margin-no tumor seen.

GROSS DESCRIPTION:

A. LEVEL 7 SUBCARINAL

Received fresh are multiple tan-black fragments of soft tissue, 1.0 x 0.5 x 0.2 cm. Touch preps are made and the specimen is submitted in toto in FSA1.

B. 4L LYMPH NODE

[page 2 of 5]
[REDACTED]

Is a tan-black soft tissue fragment, 0.3 x 0.3 x 0.2 cm. Touch preps are taken and the specimen is submitted in toto in FSB1.

C. 2ND 4L LYMPH NODE

Are multiple tan-red fragments of soft tissue aggregating to 1.0 x 0.5 x 0.2 cm. Touch preps are taken and the specimen is submitted in toto in FSC1.

D. 4R LYMPH NODE

Are multiple tan-purple fragments of soft tissue aggregating to 1.3 x 1.0 x 0.3 cm. Touch preps are taken and the specimen is submitted in toto in FSD1.

E. 2R LYMPH NODE

Are multiple tan-red fragments of soft tissue, 0.8 x 0.3 x 0.2 cm. Touch preps are taken and the specimen is submitted in toto in FSE1.

F. 11R LYMPH NODE LOWER LOBE

Are 3 tan-pink possible lymph nodes ranging from 0.5 x 0.4 x 0.4 cm to 1.0 x 0.6 x 0.5 cm. The specimen is submitted entirely as follows:

F1: 2 possible lymph nodes

F2: largest lymph node trisected

G. 11R MIDDLE LOBE

Are 2 tan-pink lymph nodes, 0.6 x 0.5 x 0.5 cm and 1.0 x 0.8 x 0.6 cm. The specimen is submitted entirely in cassette G1.

H. LEVEL 7

Are 3 tan-pink lymph nodes ranging from 0.6 x 0.4 x 0.4 cm to 2.0 x 1.0 x 1.0 cm. The specimen is submitted entirely as follows:

H1: 2 possible lymph nodes

H2: 1 lymph node serially sectioned

I. POSTERIOR PARTIAL RIGHT LOWER LOBE ATTACHMENTS OF TUMOR

Unoriented tan-pink membranous soft tissue fragment, 4.0 x 3.0 x 0.4 cm. The specimen is serially sectioned and submitted in toto in cassette I1-I3.

[REDACTED]

J. RIGHT LOWER LOBE

Is a 315 gm right lower lobe measuring 17 x 12 x 4.5 cm. The bronchial margin is shaved and submitted for frozen section in FSJ1. The pleural surface is red-purple, is remarkable for a gray-white discolored firm area located at the periphery measuring 9.0 x 8.0 cm. The pleural surface surrounding this area is inked blue and the specimen is serially sectioned to reveal a gray-white well circumscribed firm mass with a maximum depth of 3.5 cm, measuring 5.0 cm from the bronchial margin and abuts the pleural surface. The remainder lung parenchyma is red-purple and grossly unremarkable. 5 possible hilar lymph nodes are identified, the largest of which measures 0.8 cm in greatest dimension. A portion of the specimen is submitted for tissue procurement. Representative sections are submitted as follows:

FSJ1: bronchial margin submitted for frozen section

J2-J29: entire tumor with adjacent parenchyma and pleural margin

J30-J31: representative section of uninvolved lung parenchyma

J32: 5 possible hilar lymph nodes

[REDACTED]

[page 3 of 5]
DIAGNOSIS:

A. LYMPH NODE, LEVEL 7 SUBCARINAL, BIOPSY:

- ONE FRAGMENTED LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

B. LYMPH NODE, 4L, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

C. LYMPH NODE, SECOND 4L, BIOPSY:

- ONE FRAGMENTED LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

D. LYMPH NODE, 4R, BIOPSY:

- ONE FRAGMENTED LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

E. LYMPH NODE, 2R, BIOPSY:

- ONE FRAGMENTED LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

F. LYMPH NODE, 11R LOWER LOBE, BIOPSY:

- THREE LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).

G. LYMPH NODE, 11R MIDDLE LOBE, BIOPSY:

- TWO LYMPH NODES NEGATIVE FOR CARCINOMA (0/2).

H. LYMPH NODE, LEVEL 7, BIOPSY:

- THREE LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).

I. RIGHT LUNG, POSTERIOR PARTIAL LOWER LOBE ATTACHMENTS OF TUMOR, RESECTION:

- PLEURAL AND SOFT TISSUE WITH CHRONIC INFLAMMATION AND FIBROVASCULAR ADHESIONS.
- INCIDENTAL NODULULAR LANGERHANS CELL PROLIFERATION
- SEE COMMENT.
- NEGATIVE FOR CARCINOMA.

J. RIGHT LUNG, LOWER LOBE, LOBECTOMY:

- INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH MARKED CLEAR CELL CHANGE.
- TUMOR IS 9.0 CM IN MAXIMUM DIMENSION
- BRONCHIAL MARGIN IS FREE OF TUMOR
- PERITUMORAL OBSTRUCTIVE CHANGES AND INFLAMMATION.
- SUBPLEURAL AND INTERSTITIAL FIBROSIS WITH PLEURAL FIBROVASCULAR ADHESIONS.
-

[page 4 of 5]
COMMENT: In the biopsy from the pleura there is a microscopic nodule of Langerhans cells and accompanying eosinophils. The significance of this is not clear, but it is possible that the patient has an underlying pulmonary Langerhans cell histiocytosis (PLCH) related to tobacco use. There is scarring in the accompanying lung tissue which could be related to this process, but definitive evidence of PLCH in the lung is not otherwise seen.

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: J: RIGHT LOWER LOBE

Surgical Procedure: Lobectomy

Laterality: Right

Tumor Site: Lower lobe

Tumor Location: Peripheral

Tumor Size: Greatest diameter: 9cm

Additional dimensions: 8cm x 3.5cm

WHO CLASSIFICATION

Squamous cell carcinoma

Histologic Grade: G2: Moderately differentiated

Angiolymphatic Invasion: Indeterminate

Bronchial Margins: Bronchial margins uninvolved

Tumor Distance from margin: 5cm

Visceral Pleural Involvement: Present (pT2)

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)

Negative 0 / 5

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)

Negative 0 / 6

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular

Negative 0 / 2

Non-Neoplastic Lung: Obstructive changes, subpleural and interstitial scarring.

Additional Pathologic Findings: Inflammation

Type: Chronic

Pathological Staging (pTNM): pT 2 N 0 M x

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block I2

Population: Langerhans Cells

Stain/Marker:	Result:	Comment:
CD1A	Positive	
S-100	Positive	

[page 5 of 5]
The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry [REDACTED]. The use of one or more reagents in the above tests is regulated as an

[REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

1

Source: NCI Genomic Data Commons file a332c5c4-0b47-4549-8734-a1af753c2ee6 (TCGA-60-2711.EFC8DEDF-808C-4872-87A0-4249493F59B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).